MMRF case MMRF_1589 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/8a90e712-3efe-4911-80f2-f030eca424b7

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 51 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 51.8 years (18,917 days); ISS stage: I; Days to last known disease status: 1,267 days (3.5 years); Days to last follow up: 1,267 days (3.5 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 128 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 134 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 162 days; Days to treatment end: 162 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 162 days; Days to treatment end: 196 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 167 days; Days to treatment end: 196 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 197 days; Days to treatment end: 197 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 273 days; Days to treatment end: 567 days (1.6 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 610 days (1.7 years); Days to treatment end: 1,211 days (3.3 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -14: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 16.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.804 mg/dL; Immunoglobulin G 7.35 g/L; Immunoglobulin A 1.95 g/L; Immunoglobulin M 0.6 g/L; Beta 2 Microglobulin 2.29 µg/mL; Lactate Dehydrogenase 3.02 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 269 ×10⁹/L; Creatinine 77 µmol/L; Blood Urea Nitrogen 7 mmol/L; Calcium 2.46 mmol/L; Albumin 47 g/L; Total Protein 7.3 g/dL; Glucose 6.1 mmol/L; C-Reactive Protein 0.52 mg/dL.
- Day 78 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.68 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.05 mg/dL; Lactate Dehydrogenase 2.43 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 223 ×10⁹/L; Creatinine 57 µmol/L; Blood Urea Nitrogen 6.9 mmol/L; Calcium 2.32 mmol/L; Albumin 44 g/L; Total Protein 7.2 g/dL; Glucose 10.7 mmol/L.
- Day 152 (ECOG 1): M Protein 1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.35 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.1 mg/dL; Immunoglobulin G 4.54 g/L; Immunoglobulin A 0.87 g/L; Immunoglobulin M 0.39 g/L; Beta 2 Microglobulin 1.49 µg/mL; Lactate Dehydrogenase 3.5 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 19.1 ×10⁹/L; Absolute Neutrophil 16.3 ×10⁹/L; Platelets 193 ×10⁹/L; Creatinine 67 µmol/L; Blood Urea Nitrogen 4.4 mmol/L; Calcium 2.35 mmol/L; Albumin 38 g/L; Total Protein 7 g/dL; Glucose 10.5 mmol/L.
- Day 250 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.25 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.08 mg/dL; Immunoglobulin G 10.6 g/L; Immunoglobulin A 1.6 g/L; Immunoglobulin M 0.28 g/L; Beta 2 Microglobulin 1.65 µg/mL; Lactate Dehydrogenase 3.03 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 294 ×10⁹/L; Creatinine 80 µmol/L; Blood Urea Nitrogen 3.9 mmol/L; Calcium 2.22 mmol/L; Albumin 37 g/L; Total Protein 7 g/dL; Glucose 9.3 mmol/L.
- Day 329 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.29 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.12 mg/dL; Immunoglobulin G 10.4 g/L; Immunoglobulin A 1.47 g/L; Immunoglobulin M 0.44 g/L; Beta 2 Microglobulin 1.7 µg/mL; Lactate Dehydrogenase 2.57 µkat/L; Hemoglobin 9.05 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 242 ×10⁹/L; Creatinine 88 µmol/L; Blood Urea Nitrogen 4 mmol/L; Calcium 2.29 mmol/L; Albumin 44 g/L; Total Protein 7.8 g/dL; Glucose 10 mmol/L.
- Day 422 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.891 mg/dL; Immunoglobulin G 11.1 g/L; Immunoglobulin A 1.76 g/L; Immunoglobulin M 0.53 g/L; Lactate Dehydrogenase 2.65 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 233 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 6.1 mmol/L; Calcium 2.36 mmol/L; Albumin 45.2 g/L; Total Protein 7.8 g/dL; Glucose 12.8 mmol/L.
- Day 518 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.913 mg/dL; Immunoglobulin G 11.1 g/L; Immunoglobulin A 2 g/L; Immunoglobulin M 0.48 g/L; Lactate Dehydrogenase 3.63 µkat/L; Hemoglobin 8.87 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 217 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.44 mmol/L; Albumin 44.6 g/L; Total Protein 7.5 g/dL; Glucose 6.6 mmol/L.
- Day 616 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.88 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.37 mg/dL; Immunoglobulin G 10.2 g/L; Immunoglobulin A 2.24 g/L; Immunoglobulin M 0.86 g/L; Lactate Dehydrogenase 3.32 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 274 ×10⁹/L; Creatinine 78 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.43 mmol/L; Albumin 45 g/L; Total Protein 8.2 g/dL; Glucose 13.8 mmol/L.
- Day 686 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.87 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.969 mg/dL; Immunoglobulin G 11.7 g/L; Immunoglobulin A 2.31 g/L; Immunoglobulin M 0.57 g/L; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 8.87 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 239 ×10⁹/L; Creatinine 70 µmol/L; Blood Urea Nitrogen 4.4 mmol/L; Calcium 2.34 mmol/L; Albumin 42 g/L; Total Protein 7.6 g/dL; Glucose 11.6 mmol/L.
- Day 798 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.42 mg/dL; Immunoglobulin G 11.3 g/L; Immunoglobulin A 2.18 g/L; Immunoglobulin M 0.48 g/L; Lactate Dehydrogenase 2.73 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 238 ×10⁹/L; Creatinine 82 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 7.2 g/dL; Glucose 9.8 mmol/L.
- Day 861 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.07 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.62 mg/dL; Immunoglobulin G 12.7 g/L; Immunoglobulin A 2.4 g/L; Immunoglobulin M 0.67 g/L; Lactate Dehydrogenase 2.4 µkat/L; Hemoglobin 9.18 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 250 ×10⁹/L; Creatinine 78 µmol/L; Blood Urea Nitrogen 5.5 mmol/L; Calcium 2.34 mmol/L; Albumin 39 g/L; Total Protein 7.6 g/dL; Glucose 8.2 mmol/L.
- Day 980 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.19 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.52 mg/dL; Immunoglobulin G 11.1 g/L; Immunoglobulin A 2.25 g/L; Immunoglobulin M 0.42 g/L; Lactate Dehydrogenase 2.78 µkat/L; Hemoglobin 8.99 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 216 ×10⁹/L; Creatinine 75 µmol/L; Blood Urea Nitrogen 5.2 mmol/L; Calcium 2.34 mmol/L; Albumin 41 g/L; Total Protein 7.6 g/dL; Glucose 10.4 mmol/L.
- Day 1,092 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.83 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.21 mg/dL; Immunoglobulin G 12.4 g/L; Immunoglobulin A 0.51 g/L; Immunoglobulin M 0.51 g/L; Lactate Dehydrogenase 2.37 µkat/L; Hemoglobin 9.05 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 213 ×10⁹/L; Creatinine 80 µmol/L; Blood Urea Nitrogen 5.4 mmol/L; Calcium 2.31 mmol/L; Albumin 43.8 g/L; Total Protein 7.3 g/dL; Glucose 12.8 mmol/L.
- Day 1,155 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.25 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.4 mg/dL; Immunoglobulin G 11.9 g/L; Immunoglobulin A 2.47 g/L; Immunoglobulin M 0.47 g/L; Lactate Dehydrogenase 3.37 µkat/L; Hemoglobin 9.55 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 184 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 5.5 mmol/L; Calcium 2.24 mmol/L; Albumin 43 g/L; Total Protein 7.8 g/dL; Glucose 10.4 mmol/L.
- Day 1,267 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.47 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.23 mg/dL; Immunoglobulin G 10.3 g/L; Immunoglobulin A 2.17 g/L; Immunoglobulin M 0.62 g/L; Lactate Dehydrogenase 3.02 µkat/L; Hemoglobin 8.93 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 216 ×10⁹/L; Creatinine 83 µmol/L; Blood Urea Nitrogen 6.6 mmol/L; Calcium 2.38 mmol/L; Albumin 41 g/L; Total Protein 7.4 g/dL; Glucose 9.1 mmol/L.

Other clinical attributes
- Day -14: Weight: 112 kg; Height: 178 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1589_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -14 days.
- Sample MMRF_1589_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -14 days.
